Somatic mutation profile of tumor specimen ALCH-B0DY-TTP1-A (aliquot ALCH-B0DY-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B0DY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.4 years (26,074 days).
Specimen ALCH-B0DY-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0bed90c-2196-41cc-a63b-84165c0acf7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0DY-NB1-A (Blood Derived Normal), aliquot ALCH-B0DY-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d609fc0-896f-479f-8e39-ae067819f110

The open-access MAF lists 123 somatic variants for this specimen: 87 protein-altering or splice-affecting, 28 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 28, Nonsense Mutation 9, Intron 4, Frame Shift Del 3, RNA 2, Splice Site 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 35/118 reads (30%) | catalogued as rs121913383, COSV58683264, COSV58724303, COSV58727969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXP2 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 75/475 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs121908377, CM012948, COSV63496423; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 16/94 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 22/92 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- ACAN | c.5560G>A p.E1854K | Missense Mutation (SNP) | VAF 63/482 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs780061518, COSV61358186; called by muse, mutect2, varscan2
- AKAP11 | c.3955A>G p.I1319V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99214488; called by muse, mutect2, varscan2
- C1S | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 59/371 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs782354572; called by muse, mutect2, varscan2
- CCDC9B | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as rs1371379948; called by muse, mutect2, varscan2
- CDK8 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV67423403; called by muse, mutect2, varscan2
- CELSR1 | c.6691G>A p.V2231M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs770672966; called by muse, mutect2, varscan2
- CHST2 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.765); catalogued as COSV58886674; called by muse, mutect2, varscan2
- CKAP2 | c.865G>A p.E289K (on ENST00000378037 / NM_001098525.2; = p.E288K on NM_018204.5) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as COSV51621706; called by muse, mutect2, varscan2
- CNR1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs868306589, COSV100759337; called by muse, mutect2, varscan2
- EPHA6 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV67567200; called by muse, mutect2, varscan2
- ITGA8 | c.1226C>G p.P409R | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65226001; called by muse, mutect2, varscan2
- KIRREL3 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM125538, COSV101585898, COSV73109763; called by muse, mutect2
- LPCAT3 | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | catalogued as COSV54641925; called by muse, mutect2, varscan2
- MYH14 | c.4634A>G p.H1545R | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1435411739; called by muse, varscan2
- MYH4 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs149818821; called by muse, mutect2, varscan2
- PLSCR2 | c.734G>T p.G245V (on ENST00000497985 / NM_001199978.1; = p.G172V on NM_020359.2) | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60865034; called by muse, mutect2, varscan2
- PPP1R9B | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as rs764746064, COSV100380743; called by muse, mutect2, varscan2
- RASGRP2 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV100818370; called by muse, mutect2, varscan2
- RFPL2 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99963926; called by muse, mutect2, varscan2
- SLC47A1 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 63/388 reads (16%) | catalogued as COSV54499818; called by muse, mutect2, varscan2
- SLIT1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as rs772450910, COSV56593410; called by muse, varscan2
- SNTG1 | c.163-2A>C p.X55_splice | Splice Site (SNP) | VAF 31/254 reads (12%) | catalogued as COSV52447855; called by muse, mutect2, varscan2
- SORCS1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV53880380, COSV53904652; called by muse, mutect2, varscan2
- SPG11 | c.3752G>T p.G1251V | Missense Mutation (SNP) | VAF 89/473 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as COSV99968529; called by muse, mutect2, varscan2
- SVIL | c.2876G>A p.R959Q (on ENST00000355867 / NM_021738.3; = p.R533Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs769551798; called by muse, mutect2, varscan2
- THOC1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs1250711792, COSV99863634; called by muse, mutect2
- THSD7B | c.3817C>T p.R1273W (on ENST00000272643; = p.R1271W on NM_001316349.2) | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200780753; called by muse, mutect2, varscan2
- TSNARE1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs148903424; called by muse, mutect2, varscan2
- USP36 | c.2312C>T p.T771M | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs751174118, COSV61750201; called by muse, mutect2
- VPS39 | c.242A>G p.H81R (on ENST00000348544 / NM_001301138.2; = p.H70R on NM_015289.5) | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs1463949198; called by muse, mutect2, varscan2
- ZCCHC4 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs747182175; called by muse, mutect2, varscan2
- ZNF527 | c.604C>A p.Q202K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769051828; called by muse, mutect2, varscan2
- ZNF773 | c.521C>A p.S174* | Nonsense Mutation (SNP) | VAF 46/210 reads (22%) | catalogued as COSV99989082; called by mutect2, varscan2
- ZNF880 | c.1505G>T p.S502I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as COSV69906163; called by muse, mutect2, varscan2
- AC098582.1 | c.2779G>T p.V927L | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ATP13A3 | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- BEND6 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 36/325 reads (11%) | called by muse, mutect2, varscan2
- BRAF | c.633C>A p.D211E | Missense Mutation (SNP) | VAF 65/398 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- CDT1 | c.1348C>A p.R450S | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CFAP92 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.241); called by muse, mutect2
- COL11A2 | c.3988G>A p.G1330R (on ENST00000341947 / NM_080680.3; = p.G1223R on NM_080679.2) | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- CSNK1E | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CXCR1 | c.539del p.P180Qfs*62 | Frame Shift Del (DEL) | VAF 60/373 reads (16%) | called by mutect2, pindel, varscan2
- DDRGK1 | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- DDX60L | c.4795G>T p.G1599C | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, mutect2
- DEFB106A | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC10 | c.1290A>T p.E430D | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO45 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.029); called by muse, mutect2
- FCGBP | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- FNDC1 | c.1291T>C p.Y431H | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- H2BC10 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- IPO11 | c.2698C>G p.L900V | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNQ2 | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KIF15 | c.731T>A p.I244K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- KMT2A | c.1228A>G p.I410V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LAMA5 | c.5210T>C p.L1737P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRA4 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRCC1 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2
- MUC5B | c.6444C>A p.N2148K | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- NALCN | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- NIPAL1 | c.513A>T p.K171N | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRC4 | c.2616C>G p.I872M | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2
- NOLC1 | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NXPH3 | c.741dup p.Y248Lfs*71 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- OPRK1 | c.289T>G p.Y97D | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4C5 | c.776T>A p.V259E | Missense Mutation (SNP) | VAF 85/513 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OVCH2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLSCR2 | c.733G>T p.G245C (on ENST00000497985 / NM_001199978.1; = p.G172C on NM_020359.2) | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SAMD5 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3B1 | c.2819T>C p.L940S | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SFTPA1 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIPA1L2 | c.3522A>C p.E1174D | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC13A4 | c.1318+2T>C p.X440_splice | Splice Site (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- SORCS1 | c.3079G>A p.G1027S | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SPATA20 | c.1415del p.L472Wfs*40 (on ENST00000356488 / NM_001258372.1; = p.L488Wfs*40 on NM_022827.4) | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, varscan2
- SPDYE6 | c.661T>C p.S221P | Missense Mutation (SNP) | VAF 16/616 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ST14 | c.1790C>G p.S597* | Nonsense Mutation (SNP) | VAF 36/209 reads (17%) | called by muse, mutect2, varscan2
- STAT3 | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 88/633 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- TAOK2 | c.3379_3389del p.L1127Wfs*6 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel
- TRIM43B | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 18/312 reads (6%) | called by muse, mutect2
- TULP1 | c.88C>A p.R30S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- UBC | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 76/458 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ZSCAN31 | c.1199T>G p.I400S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD17 | c.5319C>T p.I1773= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- APOF | c.447G>T p.L149= | Silent (SNP) | VAF 29/260 reads (11%) | called by mutect2, varscan2
- CACNA1G | c.2181C>T p.A727= | Silent (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- CATSPER3 | c.555C>T p.F185= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as rs1343176734; called by muse, mutect2, varscan2
- CDKN1A | c.87G>A p.Q29= | Silent (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- CLDN9 | c.219G>C p.L73= | Silent (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- DDX60L | c.4794C>T p.V1598= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as rs1241545760; called by muse, mutect2
- FLT4 | c.570C>A p.G190= | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- GLDC | c.2673C>T p.H891= | Silent (SNP) | VAF 47/356 reads (13%) | catalogued as rs144939090, COSV58680418; called by muse, mutect2, varscan2
- LPCAT3 | c.865C>T p.L289= | Silent (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- OR4Q2 | c.363C>T p.Y121= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs748525754; called by muse, mutect2, varscan2
- PABPC1L | c.252C>T p.I84= | Silent (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- PENK | c.261T>C p.N87= | Silent (SNP) | VAF 58/391 reads (15%) | catalogued as rs1004308282; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIGO | c.1107C>T p.L369= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs894528056; called by muse, mutect2
- PLG | c.930A>G p.T310= | Silent (SNP) | VAF 28/206 reads (14%) | called by muse, mutect2
- RAB21 | c.354G>A p.R118= | Silent (SNP) | VAF 39/292 reads (13%) | catalogued as rs777918433; called by muse, mutect2, varscan2
- RBP3 | c.2937G>A p.V979= | Silent (SNP) | VAF 32/197 reads (16%) | called by muse, mutect2, varscan2
- RNF214 | c.591G>A p.L197= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- SCN2A | c.5319G>C p.A1773= | Silent (SNP) | VAF 53/417 reads (13%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.1683C>A p.A561= | Silent (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- TNFSF4 | c.237C>T p.S79= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2
- TRIB3 | c.114G>C p.G38= | Silent (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- TUBA3D | c.78T>A p.L26= | Silent (SNP) | VAF 24/160 reads (15%) | called by muse, mutect2, varscan2
- UGGT1 | c.1563T>A p.L521= | Silent (SNP) | VAF 42/258 reads (16%) | called by muse, mutect2, varscan2
- UMOD | c.561C>A p.T187= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV56778421; called by mutect2, varscan2
- UNC80 | c.3282C>G p.L1094= | Silent (SNP) | VAF 40/265 reads (15%) | called by muse, mutect2, varscan2
- USP51 | c.1239G>C p.S413= | Silent (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- ZEB2 | c.3591G>C p.G1197= | Silent (SNP) | VAF 48/281 reads (17%) | catalogued as COSV57962883; called by muse, mutect2, varscan2
- AC107023.1 | n.25+5496G>A | Intron (SNP) | VAF 36/178 reads (20%) | catalogued as rs771719414; called by muse, mutect2, varscan2
- ALG6 | c.*48C>T | 3'UTR (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2
- CHCHD2P9 | n.29C>T | RNA (SNP) | VAF 11/99 reads (11%) | catalogued as rs1188357072; called by muse, mutect2, varscan2
- DCHS2 | n.7042A>C | RNA (SNP) | VAF 28/243 reads (12%) | called by muse, mutect2, varscan2
- DOCK10 | c.124-15284del | Intron (DEL) | VAF 11/110 reads (10%) | called by mutect2, pindel, varscan2
- IKZF1 | c.161-8274G>A | Intron (SNP) | VAF 54/442 reads (12%) | catalogued as rs148745500; called by muse, mutect2, varscan2
- P3H3 | c.-4C>T | 5'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- STK36 | c.2587-167G>T | Intron (SNP) | VAF 24/189 reads (13%) | called by muse, mutect2, varscan2
